Gene-level copy-number profile of tumor specimen TCGA-30-1853-01A from TCGA case TCGA-30-1853, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.6 years (21,404 days).
Specimen TCGA-30-1853-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d27694d2-11bd-4504-9546-564c20cb6832.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-30-1853-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c571273d-89e5-46a8-9ab2-1b2041f38951

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 7,281; copy number 2: 23,329; copy number 3: 24,672; copy number 4: 2,147; copy number 5: 1,004; copy number 6: 1,105; copy number 7: 30; copy number 8: 145; copy number 16: 57; copy number 22: 33; copy number 23: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-30-1853-01A-02D-0648-01): tumor purity 1, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 279 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:32,728,569–34,299,012, 30 genes, copy number 7 (within-gene range 4–7): ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1, FKBP9, RNU6-388P, NT5C3A, RPS29P14, RN7SL505P, RP9, BBS9, AC074338.1, RNA5SP229, AC007312.1, AC006195.1, AC008080.1, AC008080.2, AC008080.4, AC008080.3, BMPER, AC007350.1, AC009262.1.
- chr18:22,088,060–27,595,164, 104 genes, copy number 16–23 (broad region; genes not listed).
- chr19:12,945,855–15,950,350, 145 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
